Somatic mutation profile of tumor specimen TCGA-D7-6818-01A (aliquot TCGA-D7-6818-01A-11D-1882-08) from TCGA case TCGA-D7-6818, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 53.1 years (19,391 days).
Specimen TCGA-D7-6818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfd70484-dd70-4659-99ff-dba298b35352.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6818-10A (Blood Derived Normal), aliquot TCGA-D7-6818-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44adc037-e1fe-41cd-8150-01aee8c9af39

The open-access MAF lists 169 somatic variants for this specimen: 137 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 29, Frame Shift Del 5, Nonsense Mutation 2, Frame Shift Ins 1, 3'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs1004981575, COSV59582892, COSV59590977; called by muse, mutect2, varscan2
- ACOX1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762956777, COSV53136333; called by muse, mutect2, varscan2
- ACSM2A | c.584A>G p.K195R (on ENST00000219054; = p.K116R on NM_001308169.2) | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV54586469, COSV54589383; called by muse, mutect2, varscan2
- ACTN1 | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1254713171, COSV51996936; called by muse, mutect2, varscan2
- ADAMTS12 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV61277509; called by muse, mutect2, varscan2
- ADCY2 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV57857206, COSV57864358; called by muse, mutect2, varscan2
- ADGRB3 | c.3140T>C p.L1047P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53253255, COSV53258799; called by muse, mutect2, varscan2
- AJAP1 | c.749T>G p.V250G | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV65451938; called by muse, mutect2, varscan2
- AKAP6 | c.5947T>C p.S1983P | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55231317; called by muse, mutect2, varscan2
- AKR1C4 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as rs528399704, COSV54125348; called by muse, mutect2, varscan2
- ALAD | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs371983646; called by muse, mutect2, varscan2
- ALG10 | c.322T>C p.F108L | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as COSV56794051; called by muse, mutect2, varscan2
- ANGPT1 | c.1414A>G p.N472D | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV52455589; called by muse, mutect2, varscan2
- ANKFY1 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV100492463, COSV58922326; called by muse, mutect2, varscan2
- ARMC3 | c.1637A>C p.K546T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.621); catalogued as COSV53067012; called by muse, mutect2, varscan2
- BCL9L | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs377431418, COSV52688794; called by muse, mutect2, varscan2
- BRINP1 | c.832T>C p.C278R | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56312135; called by muse, mutect2, varscan2
- BRWD1 | c.2618G>A p.G873D | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370519269, COSV60902278; called by muse, mutect2, varscan2
- C12orf50 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV53893493; called by muse, mutect2, varscan2
- C16orf92 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs370643656, COSV54228068; called by muse, mutect2, varscan2
- CD163L1 | c.2108T>G p.V703G | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58023900; called by muse, mutect2, varscan2
- CD84 | c.981A>C p.K327N (on ENST00000311224 / NM_001184879.2; = p.K310N on NM_003874.4) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV60870619; called by muse, mutect2, varscan2
- CDR1 | c.357A>C p.E119D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV65164742; called by muse, mutect2, varscan2
- CFAP206 | c.1843T>G p.L615V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65810102; called by muse, mutect2
- CNGA4 | c.1529A>C p.K510T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV66005440; called by muse, mutect2, varscan2
- CSMD1 | c.9109A>C p.S3037R (on ENST00000520002; = p.S3036R on NM_033225.6) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV59371406, COSV59377456; called by muse, mutect2, varscan2
- CSMD2 | c.4472A>C p.N1491T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV53957473; called by muse, mutect2
- DAB2 | c.1361T>G p.L454R | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV57918652; called by muse, mutect2, varscan2
- DDX49 | c.323T>C p.M108T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV53232280; called by muse, mutect2, varscan2
- DENND4C | c.4058A>C p.K1353T (on ENST00000434457 / NM_001330640.2; = p.K1304T on NM_017925.7) | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs144390071; called by muse, mutect2, varscan2
- DLX5 | c.432T>G p.Y144* | Nonsense Mutation (SNP) | VAF 41/155 reads (26%) | catalogued as COSV56034194; called by muse, mutect2, varscan2
- DMD | c.4088A>C p.K1363T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as COSV63732568, COSV63756777; called by muse, mutect2, varscan2
- DNAH1 | c.10771G>A p.V3591M | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs755963386, COSV70235569; called by muse, mutect2, varscan2
- DOCK4 | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV70326031; called by muse, mutect2
- DYNC2H1 | c.10062A>C p.Q3354H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV62105738; called by muse, mutect2, varscan2
- ERV3-1 | c.1214T>A p.L405H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV99275917, COSV99275962, COSV99276117; called by muse, mutect2, varscan2
- FAT4 | c.6028A>G p.S2010G | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.221); catalogued as rs1406220429, COSV100629450, COSV58706267; called by muse, mutect2, varscan2
- FCGBP | c.6994T>G p.F2332V | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV55452981; called by muse, mutect2
- FLG2 | c.1651A>C p.S551R | Missense Mutation (SNP) | VAF 316/587 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV66166341, COSV66166598; called by muse, mutect2, varscan2
- FNDC3B | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.897); catalogued as COSV61048861; called by muse, mutect2, varscan2
- FOXI1 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1056161920, COSV60388018, COSV60389889; called by muse, mutect2, varscan2
- GPR137 | c.961T>G p.F321V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57403814; called by muse, mutect2, varscan2
- H1-4 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs766435782, COSV56803368; called by muse, mutect2
- HHIPL1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756859875, COSV58089686; called by muse, mutect2
- HMGCLL1 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51442476, COSV51451307; called by muse, mutect2, varscan2
- HTR1D | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs553069366, COSV58449093; called by muse, mutect2, varscan2
- IFI44L | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.744); catalogued as rs780019224, COSV60729239; called by muse, mutect2, varscan2
- IPO11 | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57581419; called by muse, mutect2, varscan2
- ITPKB | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV55269127; called by muse, mutect2, varscan2
- ITPRID1 | c.1825T>G p.F609V | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV60081985; called by muse, mutect2, varscan2
- JAKMIP2 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV54614609; called by muse, mutect2, varscan2
- KCNB2 | c.710A>T p.E237V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73052770; called by muse, mutect2, varscan2
- KCNMB2 | c.453T>G p.N151K | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV64201510; called by muse, mutect2, varscan2
- KRT73 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV59841552; called by muse, mutect2, varscan2
- LHX3 | c.436G>A p.E146K (on ENST00000371748 / NM_178138.6; = p.E151K on NM_014564.5) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV65583249; called by muse, mutect2, varscan2
- LIPG | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs758552549, COSV54298012; called by muse, mutect2, varscan2
- LRFN5 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53245388, COSV53273192; called by muse, mutect2, varscan2
- LRP2 | c.10352C>A p.P3451Q | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55571679; called by muse, mutect2, varscan2
- LRRIQ1 | c.1255A>C p.K419Q | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV67837699; called by muse, mutect2
- MAGEA11 | c.328A>G p.I110V | Missense Mutation (SNP) | VAF 85/134 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1557362406, COSV60758495; called by muse, mutect2, varscan2
- MAGEB6 | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.295); catalogued as rs781192763, COSV66873006; called by muse, mutect2, varscan2
- MAGEC1 | c.2061T>G p.D687E | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.182); catalogued as COSV53580467; called by muse, mutect2, varscan2
- MB21D2 | c.817T>G p.L273V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66665812; called by muse, mutect2
- MICAL1 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs764211710, COSV57806462; called by muse, mutect2, varscan2
- MKI67 | c.9250C>T p.P3084S | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.111); catalogued as rs528824310, COSV64076608; called by muse, mutect2, varscan2
- MMS22L | c.2555A>T p.Q852L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51526122; called by muse, mutect2, varscan2
- MPIG6B | c.11T>C p.F4S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.06); catalogued as COSV65390293; called by muse, mutect2, varscan2
- MPRIP | c.2519C>G p.A840G | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57930163; called by muse, mutect2
- MUC16 | c.24568A>G p.S8190G | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV101200537; called by muse, mutect2, varscan2
- MUC4 | c.16175G>A p.R5392H (on ENST00000463781 / NM_018406.7; = p.R1156H on NM_004532.6) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs754106095, COSV57771332; called by muse, mutect2, varscan2
- MYH11 | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55559326; called by muse, mutect2, varscan2
- MYOM3 | c.3993G>T p.K1331N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV58396885, COSV58400347; called by muse, mutect2, varscan2
- NAALAD2 | c.234A>C p.Q78H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV58965676; called by muse, mutect2
- NALCN | c.4472A>C p.K1491T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51962605; called by muse, mutect2, varscan2
- NALCN | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 91/140 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.632); catalogued as COSV51962622; called by muse, mutect2, varscan2
- NCOR1 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV51994439; called by muse, mutect2, varscan2
- NLRP9 | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV60467405; called by muse, mutect2, varscan2
- NRG3 | c.1091T>G p.I364S | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100930668, COSV64582202; called by muse, mutect2, varscan2
- NRK | c.261A>C p.E87D | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54605725; called by muse, mutect2
- NRK | c.4082A>G p.D1361G | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54605740; called by muse, mutect2, varscan2
- NUP155 | c.4020A>C p.Q1340H (on ENST00000231498 / NM_153485.3; = p.Q1281H on NM_004298.4) | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV51534414; called by muse, mutect2, varscan2
- OR10K2 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV59220690, COSV59222621; called by muse, mutect2, varscan2
- OR2M3 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 69/320 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs267598499, COSV71759257; called by muse, mutect2, varscan2
- OR51B5 | c.250T>C p.W84R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs887940134, COSV56177210; called by muse, mutect2, varscan2
- OR51T1 | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV59024864, COSV59027821; called by muse, mutect2, varscan2
- OR5AP2 | c.52T>G p.F18V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57258716; called by muse, mutect2, varscan2
- OR5D14 | c.579T>A p.D193E | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV59458340; called by muse, mutect2, varscan2
- PCDH15 | c.4678A>G p.S1560G | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); catalogued as COSV57386055; called by muse, mutect2, varscan2
- PCDHA6 | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.079); catalogued as COSV67080753; called by muse, mutect2, varscan2
- PDE1B | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54495934; called by muse, mutect2, varscan2
- PDE8A | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59637053, COSV59640228; called by muse, mutect2, varscan2
- PRAMEF2 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 49/426 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1063787, COSV53576618; called by muse, mutect2, varscan2
- PTPRD | c.5087G>T p.G1696V | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61928869, COSV61978655; called by muse, mutect2, varscan2
- PTPRN2 | c.1035T>A p.H345Q | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV67059066; called by muse, mutect2, varscan2
- QSOX1 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.481); catalogued as COSV62581545; called by muse, mutect2, varscan2
- RASGRP2 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs761076139, COSV62448729; called by muse, mutect2, varscan2
- RP1L1 | c.5392A>C p.S1798R | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV66759744; called by muse, mutect2, varscan2
- SALL1 | c.1768T>C p.S590P | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.69); catalogued as COSV51755058, COSV51762470; called by muse, mutect2, varscan2
- SCN7A | c.61A>C p.I21L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV69274407; called by muse, mutect2, varscan2
- SECISBP2L | c.1826T>G p.F609C (on ENST00000559471 / NM_001193489.2; = p.F564C on NM_014701.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV55937595; called by muse, mutect2, varscan2
- SIX6 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59803543; called by muse, mutect2, varscan2
- SLIT2 | c.1096A>G p.S366G | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56593198; called by muse, mutect2, varscan2
- SOX15 | c.673G>C p.G225R | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.962); catalogued as COSV51469472; called by muse, mutect2, varscan2
- SPINK5 | c.1136T>C p.L379P | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56261692; called by muse, mutect2
- SUPT7L | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV53117429, COSV99270370; called by muse, mutect2, varscan2
- SYNE1 | c.945A>C p.E315D (on ENST00000367255 / NM_182961.4; = p.E322D on NM_033071.3) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV54915960; called by muse, mutect2, varscan2
- TACR1 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs148591370; called by mutect2, varscan2
- TBC1D8B | c.2690A>G p.E897G | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV52183153; called by muse, mutect2
- THAP6 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV61009434; called by muse, mutect2, varscan2
- THSD7A | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 29/200 reads (15%) | catalogued as COSV70266202; called by muse, mutect2, varscan2
- TINAG | c.535T>A p.F179I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52514420; called by muse, mutect2, varscan2
- TLR8 | c.3085C>T p.R1029W (on ENST00000218032 / NM_138636.5; = p.R1047W on NM_016610.4) | Missense Mutation (SNP) | VAF 134/216 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54320284; called by muse, mutect2, varscan2
- TMPRSS11A | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.753); catalogued as rs554126423, COSV58360920; called by muse, mutect2, varscan2
- TNRC6A | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59361174; called by muse, mutect2, varscan2
- TTC12 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.605); catalogued as COSV59099926; called by muse, mutect2
- TUSC3 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- UGT3A1 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV57102688; called by muse, mutect2
- UNC5C | c.1400A>G p.N467S | Missense Mutation (SNP) | VAF 110/515 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs147587723, COSV71658759; called by muse, mutect2, varscan2
- USH2A | c.11624T>C p.L3875P | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV56331773, COSV56428675; called by muse, mutect2, varscan2
- USH2A | c.3463A>C p.S1155R | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs766609270, COSV56372284; called by muse, mutect2, varscan2
- UTRN | c.5759T>G p.L1920R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.13); catalogued as COSV62331877; called by muse, mutect2, varscan2
- ZFHX4 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV51454206, COSV51471359, COSV99257900; called by muse, mutect2, varscan2
- ZNF34 | c.1445A>G p.K482R | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as COSV58641159; called by muse, mutect2, varscan2
- ZNF419 | c.445A>T p.S149C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99692444; called by muse, mutect2, varscan2
- ZNF98 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV63339655; called by muse, varscan2
- ZSWIM2 | c.1447T>G p.L483V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV54573597, COSV54579154; called by muse, mutect2, varscan2
- CSAG3 | c.372A>C p.K124N | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- FCGBP | c.11791C>G p.R3931G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GOLGA4 | c.1735dup p.S579Kfs*19 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- IGHV3-16 | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV3-20 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- MAP2K7 | c.432_438delinsACGTG p.H144Qfs*5 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by pindel, varscan2*
- PPP1R26 | c.2560_2561del p.S854Qfs*116 | Frame Shift Del (DEL) | VAF 43/164 reads (26%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3078A>C p.Q1026H | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SPTBN2 | c.3544del p.R1182Vfs*37 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- TP53 | c.842_848del p.D281Afs*62 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- TTLL9 | c.46_55del p.I16Pfs*33 | Frame Shift Del (DEL) | VAF 30/324 reads (9%) | called by mutect2, pindel
- ADAMTS20 | c.4476A>G p.G1492= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV67129177; called by muse, mutect2, varscan2
- ADAMTS3 | c.2400T>A p.P800= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as COSV99711668; called by muse, mutect2
- ADAMTS9 | c.1539C>T p.I513= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV55789660; called by muse, mutect2, varscan2
- CDYL | c.642C>T p.S214= (on ENST00000328908 / NM_001368125.1; = p.S160= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs781317117, COSV59361705; called by muse, mutect2, varscan2
- CHD7 | c.1167T>G p.T389= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as COSV71111760; called by muse, mutect2, varscan2
- CUBN | c.2556A>G p.Q852= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV64710110, COSV64721355, COSV64726238; called by muse, mutect2, varscan2
- DNAH9 | c.8217T>G p.T2739= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV52374579; called by muse, mutect2, varscan2
- DNAI4 | c.2241T>A p.T747= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as COSV64031327; called by muse, mutect2, varscan2
- GAS2 | c.822C>T p.I274= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV53412284; called by muse, mutect2
- GLI3 | c.2673G>A p.V891= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV67894440; called by muse, mutect2, varscan2
- KY | c.1809T>C p.G603= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV71018603; called by muse, mutect2
- MAGEC2 | c.921A>G p.S307= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV56001250; called by muse, mutect2, varscan2
- MCC | c.270G>A p.A90= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs370838410, COSV56735621; called by muse, mutect2, varscan2
- NAV2 | c.4740C>T p.S1580= (on ENST00000396087 / NM_001244963.2; = p.S1557= on NM_145117.5) | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV60664744; called by muse, mutect2, varscan2
- NPRL3 | c.585G>A p.L195= (on ENST00000611875 / NM_001077350.3; = p.L170= on NM_001039476.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs759451803, COSV67854491; called by muse, mutect2
- NTN1 | c.822C>T p.Y274= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV51482604; called by muse, mutect2, varscan2
- OR2L2 | c.159T>C p.H53= | Silent (SNP) | VAF 38/476 reads (8%) | catalogued as COSV63560249; called by muse, mutect2
- PIK3R5 | c.1389G>A p.L463= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs767011724, COSV52657913, COSV52658336; called by muse, mutect2, varscan2
- PIP4P2 | c.459G>C p.V153= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as COSV53440696, COSV99575324; called by muse, mutect2, varscan2
- RIMS2 | c.4602T>G p.S1534= (on ENST00000666250 / NM_001348490.2; = p.S1105= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 36/221 reads (16%) | catalogued as COSV51717839, COSV51720177, COSV99156042; called by muse, mutect2, varscan2
- RTL9 | c.1164G>T p.P388= | Silent (SNP) | VAF 90/322 reads (28%) | catalogued as rs374873915, COSV71825809, COSV71826276; called by muse, mutect2, varscan2
- SATB1 | c.429T>G p.S143= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV58672459; called by muse, mutect2, varscan2
- SLC35F1 | c.382A>C p.R128= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV64509208; called by muse, mutect2, varscan2
- TAOK3 | c.1533G>T p.L511= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV66827615; called by muse, mutect2, varscan2
- THAP9 | c.66C>A p.G22= | Silent (SNP) | VAF 49/167 reads (29%) | catalogued as rs1443492401, COSV56357775; called by muse, mutect2, varscan2
- TTN | c.23263C>T p.L7755= (on ENST00000591111; = p.L6828= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV60313365; called by muse, mutect2, varscan2
- ZBTB20 | c.1212T>G p.A404= (on ENST00000474710 / NM_001164342.2; = p.A331= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV61866816; called by muse, mutect2, varscan2
- ZIC1 | c.411C>T p.A137= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs750080738, COSV51552643, COSV51554266; called by muse, mutect2, varscan2
- ZNF98 | c.1605A>G p.R535= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV63339646; called by muse, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20133T>G | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as COSV67448960; called by muse, mutect2
- TRH | c.*1A>T | 3'UTR (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100234888; called by muse, mutect2, varscan2
- ZNF322P1 | n.166T>G | RNA (SNP) | VAF 77/398 reads (19%) | called by muse, mutect2, varscan2
